Gene-level copy-number profile of specimen HCM-CSHL-0861-C25-85M from HCMI case HCM-CSHL-0861-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 65.8 years (24,023 days).
Specimen HCM-CSHL-0861-C25-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 75d0220a-514e-4d59-a713-4d3b562707c1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0861-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,747 have no estimate.
https://portal.gdc.cancer.gov/files/bd9527f8-daf2-44cf-8fa0-ac53f92a0398

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,531; copy number 2: 41,667; copy number 3: 5,343; copy number 4: 118; copy number 5: 204; copy number 6: 6; copy number 7: 7.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 217 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:33,401,478–34,895,764, 79 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr17:39,619,613–40,836,270, 67 genes, copy number 5 (broad region; genes not listed).
- chr17:40,861,303–40,975,926, 5 genes, copy number 5 (within-gene range 4–5): KRT12, KRT20, AC004231.1, KRT23, KRT39.
- chr17:40,993,430–41,041,450, 8 genes, copy number 5: KRTAP3-3, KRTAP3-2, KRTAP3-4P, KRTAP3-1, KRTAP1-5, KRTAP1-4, KRTAP1-3, KRTAP1-1.
- chr17:41,105,332–41,124,182, 3 genes, copy number 5 (within-gene range 4–5): KRTAP4-9, KRTAP4-11, KRTAP4-12.
- chr17:41,177,446–41,280,810, 14 genes, copy number 5–6: KRTAP4-2, KRTAP4-1, KRTAP4-17P, KRTAP9-1, KRTAP9-12P, KRTAP9-2, KRTAP9-3, KRTAP9-8, KRTAP9-4, KRTAP9-9, KRTAP9-6, KRTAP9-11P, KRTAP9-7, KRTAP9-10P.
- chr17:41,314,912–41,454,055, 12 genes, copy number 5: KRTAP17-1, TBC1D3P7, AC003958.1, KRT33A, KRT33B, KRT34, KRT31, AC003958.2, KRT41P, KRT37, KRT38, KRT43P.
- chr17:41,486,136–41,640,199, 12 genes, copy number 5: KRT36, KRT13, AC019349.1, KRT15, MIR6510, KRT19, LINC00974, KRT9, KRT14, KRT16, KRT17, KRT42P.
- chr17:41,712,331–41,786,931, 5 genes, copy number 5: GAST, HAP1, RNA5SP442, RN7SL399P, JUP.
- chr18:27,932,879–28,177,946, 3 genes, copy number 5: CDH2, AC110015.1, AC006249.1.
- chr20:22,371,216–22,966,063, 9 genes, copy number 6–7: AL133464.1, LINC00261, FOXA2, LNCNEF, LINC01747, AL158175.1, KRT18P3, CYB5AP4, AL353132.1.

Autosomal genes at a single copy (total copy number 1): 8,675. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
